Somatic mutation profile of tumor specimen HCM-CSHL-0076-C25-01A (aliquot HCM-CSHL-0076-C25-01A-21D-A786-36) from HCMI case HCM-CSHL-0076-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 74.8 years (27,308 days).
Specimen HCM-CSHL-0076-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6cc5acaf-57e1-41a0-85ce-716bce24ca11.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0076-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0076-C25-10A-01D-A786-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dfe7ccb1-dcf0-4fcf-bd1c-c72ca5dbe265

The open-access MAF lists 63 somatic variants for this specimen: 39 protein-altering or splice-affecting, 14 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 14, Nonsense Mutation 7, Intron 5, Frame Shift Del 2, 5'UTR 2, 3'Flank 1, RNA 1, Frame Shift Ins 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 72/938 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- SMAD4 | c.1333C>T p.R445* | Nonsense Mutation (SNP) | VAF 57/427 reads (13%) | hotspot (GDC flag); catalogued as rs377767360, CM000742, COSV61685033; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.783-1_787del p.X261_splice | Splice Site (DEL) | VAF 106/755 reads (14%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ACSM4 | c.90G>A p.W30* | Nonsense Mutation (SNP) | VAF 229/852 reads (27%) | catalogued as rs760878212; called by mutect2, varscan2
- ADCY8 | c.1693G>A p.V565M | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as rs62640020; called by muse, mutect2
- ARHGAP30 | c.3049C>T p.R1017* (on ENST00000368013 / NM_001025598.2; = p.R806* on NM_181720.3) | Nonsense Mutation (SNP) | VAF 86/325 reads (26%) | catalogued as COSV100920252; called by muse, mutect2, varscan2
- BRAT1 | c.1826G>A p.R609Q | Missense Mutation (SNP) | VAF 128/972 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1406194043, COSV61397538; called by muse, mutect2, varscan2
- CACNG3 | c.733C>T p.R245* | Nonsense Mutation (SNP) | VAF 25/208 reads (12%) | catalogued as COSV50069711; called by muse, mutect2, varscan2
- CEL | c.2002T>G p.S668A (on ENST00000673714; = p.S665A on NM_001807.6) | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); catalogued as rs2480922, COSV60827533; called by muse, varscan2
- DOCK10 | c.3961G>A p.G1321S | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT tolerated (0.83); PolyPhen probably damaging (0.999); catalogued as rs748247508; called by muse, mutect2, varscan2
- DSCAM | c.769C>T p.R257C | Missense Mutation (SNP) | VAF 30/261 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as rs542069235; called by muse, mutect2, varscan2
- EPB41L4A | c.1435C>T p.R479C | Missense Mutation (SNP) | VAF 17/177 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs201722745; called by muse, mutect2
- KBTBD8 | c.1645G>A p.V549I | Missense Mutation (SNP) | VAF 28/308 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs772686457, COSV55127499, COSV55128258; called by muse, mutect2
- LSP1 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 67/546 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs760171733; called by muse, varscan2
- NCK2 | c.835C>T p.R279C | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.586); catalogued as rs1480875247, COSV51891901; called by muse, mutect2, varscan2
- PCDHGB3 | c.1778C>T p.A593V | Missense Mutation (SNP) | VAF 34/782 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1474578874; called by muse, mutect2
- RAD17 | c.1553G>A p.G518E (on ENST00000380774 / NM_133339.2; = p.G507E on NM_002873.1) | Missense Mutation (SNP) | VAF 60/373 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as rs781628659; called by muse, mutect2, varscan2
- RYR1 | c.3556G>A p.G1186S | Missense Mutation (SNP) | VAF 112/1305 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs1568465251, COSV62089929; ClinVar: uncertain significance; called by muse, mutect2
- RYR1 | c.6988C>T p.R2330C | Missense Mutation (SNP) | VAF 85/1058 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as rs768804367, COSV100617653; called by muse, mutect2
- SENP6 | c.761C>T p.T254M | Missense Mutation (SNP) | VAF 70/561 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.628); catalogued as rs371874764; called by muse, mutect2, varscan2
- SFMBT2 | c.1879C>T p.R627C | Missense Mutation (SNP) | VAF 56/307 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs372825470; called by muse, mutect2, varscan2
- SLA | c.406C>T p.R136C (on ENST00000338087 / NM_001045556.3; = p.R176C on NM_006748.4) | Missense Mutation (SNP) | VAF 59/578 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs200511116, COSV55065123; called by muse, mutect2, varscan2
- SLC22A10 | c.653C>A p.S218Y | Missense Mutation (SNP) | VAF 45/279 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.222); catalogued as rs374740617, COSV100235794; called by muse, mutect2, varscan2
- AATF | c.1507A>T p.K503* | Nonsense Mutation (SNP) | VAF 26/252 reads (10%) | called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.4661C>T p.P1554L | Missense Mutation (SNP) | VAF 52/352 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- APOB | c.13392_13396del p.E4464Dfs*13 | Frame Shift Del (DEL) | VAF 46/290 reads (16%) | called by mutect2, pindel, varscan2
- ARHGEF10 | c.76G>A p.D26N (on ENST00000398564; = p.D2N on NM_014629.4) | Missense Mutation (SNP) | VAF 30/622 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.038); called by muse, mutect2
- GPR19 | c.951G>A p.W317* | Nonsense Mutation (SNP) | VAF 19/728 reads (3%) | called by muse, mutect2
- KIDINS220 | c.625G>A p.V209M | Missense Mutation (SNP) | VAF 15/270 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); called by muse, mutect2
- KRAS | c.119A>G p.Y40C | Missense Mutation (SNP) | VAF 269/517 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LAD1 | c.1306G>T p.V436L | Missense Mutation (SNP) | VAF 45/569 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.013); called by muse, mutect2
- LIPF | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 67/435 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- NUTM1 | c.1361A>C p.E454A | Missense Mutation (SNP) | VAF 33/262 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDRG1 | c.193T>G p.F65V | Missense Mutation (SNP) | VAF 19/179 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ROR1 | c.1993A>T p.M665L | Missense Mutation (SNP) | VAF 48/298 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SETD3 | c.841_842insG p.N281Rfs*13 | Frame Shift Ins (INS) | VAF 44/314 reads (14%) | called by mutect2, pindel, varscan2
- SPAG5 | c.1056_1086del p.S353Yfs*64 | Frame Shift Del (DEL) | VAF 61/520 reads (12%) | called by mutect2, pindel
- SUSD5 | c.397A>T p.I133F | Missense Mutation (SNP) | VAF 38/252 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- ZBTB20 | c.2020A>T p.K674* (on ENST00000474710 / NM_001164342.2; = p.K601* on NM_015642.6 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 24/474 reads (5%) | called by muse, mutect2
- ACSM4 | c.198G>A p.E66= | Silent (SNP) | VAF 152/410 reads (37%) | called by muse, mutect2, varscan2
- CILP2 | c.336C>T p.R112= | Silent (SNP) | VAF 25/534 reads (5%) | called by muse, mutect2
- CLIC6 | c.1686A>G p.Q562= (on ENST00000360731 / NM_001317009.2; = p.Q544= on NM_053277.3) | Silent (SNP) | VAF 37/341 reads (11%) | called by muse, mutect2, varscan2
- CMTM6 | c.517A>C p.R173= | Silent (SNP) | VAF 27/188 reads (14%) | called by muse, mutect2, varscan2
- COL4A1 | c.2376C>G p.S792= | Silent (SNP) | VAF 116/733 reads (16%) | catalogued as COSV65422537; called by muse, mutect2, varscan2
- GEMIN4 | c.216C>A p.I72= | Silent (SNP) | VAF 55/267 reads (21%) | called by muse, mutect2, varscan2
- MZF1 | c.1233G>A p.P411= | Silent (SNP) | VAF 96/788 reads (12%) | called by muse, mutect2, varscan2
- PRR23B | c.465C>T p.Y155= | Silent (SNP) | VAF 29/881 reads (3%) | catalogued as rs1288923649, COSV100271924, COSV61494977; called by muse, mutect2
- ROBO1 | c.3117T>C p.G1039= | Silent (SNP) | VAF 10/290 reads (3%) | called by muse, mutect2
- SORBS1 | c.678C>T p.R226= (on ENST00000361941 / NM_001034954.2; = p.R194= on NM_015385.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 36/175 reads (21%) | catalogued as rs764367722; called by muse, mutect2, varscan2
- SRPX2 | c.624G>A p.P208= | Silent (SNP) | VAF 150/1030 reads (15%) | catalogued as rs139514583; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- SSC5D | c.276C>T p.N92= | Silent (SNP) | VAF 58/452 reads (13%) | catalogued as rs764456516; called by muse, mutect2, varscan2
- TOP3B | c.429C>T p.G143= | Silent (SNP) | VAF 31/486 reads (6%) | catalogued as rs752451136, COSV100592500; called by muse, mutect2
- UNC13A | c.1965G>A p.A655= | Silent (SNP) | VAF 118/943 reads (13%) | catalogued as rs777063829, COSV53191454; called by muse, mutect2, varscan2
- AL450442.1 | n.673C>A | RNA (SNP) | VAF 25/269 reads (9%) | called by muse, mutect2
- H2BP2 | chr1:143876149 G>A | 3'Flank (SNP) | VAF 150/2428 reads (6%) | called by muse, mutect2
- HPR | c.-26C>T | 5'UTR (SNP) | VAF 112/720 reads (16%) | catalogued as rs763809585; called by muse, mutect2, varscan2
- KMT5B | c.1174+1071G>T | Intron (SNP) | VAF 28/250 reads (11%) | called by muse, mutect2, varscan2
- LGI1 | c.504-36C>T | Intron (SNP) | VAF 82/551 reads (15%) | called by muse, mutect2, varscan2
- NAV3 | c.2024-12911G>A | Intron (SNP) | VAF 45/221 reads (20%) | catalogued as rs1350071736; called by muse, mutect2, varscan2
- P2RX1 | c.525-25G>A | Intron (SNP) | VAF 26/677 reads (4%) | catalogued as rs529371862; called by muse, mutect2
- PKD1 | c.8792-26C>T | Intron (SNP) | VAF 46/916 reads (5%) | catalogued as rs368758926; called by muse, mutect2
- TMEM131L | c.-42C>T | 5'UTR (SNP) | VAF 23/149 reads (15%) | catalogued as rs574469145; called by muse, mutect2, varscan2
- ZNF747 | c.*38G>T | 3'UTR (SNP) | VAF 128/716 reads (18%) | called by muse, mutect2, varscan2
